Gene-level copy-number profile of tumor specimen TCGA-CN-4736-01A from TCGA case TCGA-CN-4736, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Tongue, NOS; Tumor grade: G2; Age at diagnosis: 70.3 years (25,683 days).
Specimen TCGA-CN-4736-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-HNSC.41065245-b1f0-487a-a8c7-8e1d2d846d3c.gene_level_copy_number.v36.tsv, workflow ASCAT2 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-CN-4736-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 407 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/c17a4f07-54ee-4e1e-9903-7c56d33edbb3

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 914; copy number 1: 8,462; copy number 2: 43,749; copy number 3: 6,462; copy number 4: 177; copy number 5: 185; copy number 6: 131; copy number 8: 52; copy number 9: 10; copy number 10: 15; copy number 11: 53; copy number 14: 6.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-CN-4736-01A-01D-1432-01): tumor purity 0.34, ploidy 2.02, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 6 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:186,354,570–186,509,361, 4 genes: AC017071.1, MED28P3, ZC3H15, DPRXP1.
- chr5:94,152,966–94,618,597, 1 gene (within-gene range 0–2): KIAA0825.
- chr15:69,803,316–69,804,046, 1 gene: GEMIN8P1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 437 genes in 11 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:143,541,768–147,517,875, 128 genes, copy number 6 (within-gene range 4–6) (broad region; genes not listed).
- chr1:149,782,671–150,697,154, 52 genes, copy number 8 (within-gene range 2–8): FCGR1A, H2BC18, AC243772.2, H3C13, H4C14, H3C14, H2AC18, H2BC19P, H2BC20P, H2AC19, H3C15, H4C15, AC239868.1, H2BC21, H2AC20, H2AC21, BOLA1, SV2A, SF3B4, MTMR11, OTUD7B, AC244033.2, AC244033.1, VPS45, PLEKHO1, AC242988.2, RN7SL480P, ANP32E, RNU2-17P, AC242988.1, CA14, APH1A, C1orf54, CIART, MRPS21, PRPF3, RPRD2, TARS2, MIR6878, ECM1, FALEC, ADAMTSL4-AS2, ADAMTSL4, MIR4257, ADAMTSL4-AS1, MCL1, RN7SL473P, RN7SL600P, AL356356.1, ENSA, U4, GOLPH3L.
- chr2:88,811,186–88,861,563, 1 gene, copy number 5 (within-gene range 2–5): AC244205.1.
- chr2:88,857,161–94,604,573, 118 genes, copy number 5 (broad region; genes not listed).
- chr6:53,219,261–55,282,620, 37 genes, copy number 9–14 (within-gene range 4–14): RNU1-136P, HMGB1P20, ELOVL5, MIR5685, RPS16P5, AL034374.1, RPL31P28, RPL31P33, RPA3P2, AL591034.1, RN7SKP256, NANOGP3, GCLC, AL033397.2, AL033397.1, LINC01564, KLHL31, AL590652.1, LRRC1, AL033384.2, MLIP, AL033384.1, MLIP-AS1, MLIP-IT1, ERHP2, AL359380.1, TINAG, TINAG-AS1, CLNS1AP1, RPL10P10, RPSAP44, KRASP1, RNU6-1023P, AL512363.1, FAM83B, AL049555.1, HCRTR2.
- chr8:46,028,804–47,736,306, 34 genes, copy number 5 (within-gene range 3–5): AC118650.1, HSPA8P13, ASNSP1, AC104576.1, ASNSP4, AC021451.1, TRIM60P15, AC021451.2, AC021451.3, LINC00293, MTND2P38, MTND1P7, RNU6-656P, MTCYBP20, MTND6P20, AC091163.3, AC091163.1, AC091163.2, MAPK6P4, RN7SKP32, AC120036.1, AC120036.5, RNU6-819P, RPL10AP2, NDUFA5P12, AC120036.3, AC120036.4, ATP6V1G1P2, AC120036.2, IGLV8OR8-1, SPIDR, AC024451.2, AC024451.4, AC024451.1.
- chr8:49,536,386–49,907,446, 4 genes, copy number 9: AC090155.1, PSAT1P1, AC113145.1, AC023762.1.
- chr15:25,065,026–25,108,352, 28 genes, copy number 11: SNORD116-6, SNORD116-7, SNORD116-8, SNORD116-9, SNORD116-10, SNORD116-11, SNORD116-12, SNORD116-13, SNORD116-14, SNORD116-15, SNORD116-16, SNORD116-17, SNORD116-18, SNORD116-19, AC124312.3, SNORD116-20, SNORD116-21, SNORD116-22, SNORD116-23, AC124312.5, AC124312.4, SNORD116-24, SNORD116-25, SNORD116-26, SNORD116-27, SNORD116-28, SNORD116-29, SNORD116-30.
- chr15:34,084,017–34,969,742, 32 genes, copy number 5: EMC7, AC079203.1, PGBD4, KATNBL1, EMC4, SLC12A6, AC079203.2, Y_RNA, NOP10, NUTM1, LPCAT4, ACTG1P15, GOLGA8A, MIR1233-1, AC025678.1, AC025678.2, AC025678.3, HNRNPLP2, FSCN1P1, DNM1P5, GOLGA8B, MIR1233-2, AC027139.1, AC100834.1, LINC02252, AC100834.2, GJD2, AC087457.1, ACTC1, TUBAP11, AQR, AC018868.1.
- chr15:71,332,120–71,352,460, 2 genes, copy number 6: AC064799.2, AC064799.1.
- chr20:23,583,645–23,586,510, 1 gene, copy number 6 (within-gene range 3–6): CST9LP2.

Autosomal genes at a single copy (total copy number 1): 7,727. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
